CCDI case PBBMIZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/6159e46d-53cc-4ebd-8954-8f3a20db3882

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 8.0 years (2,939 days).

Biospecimens (3 samples)
- Sample 0DCX8Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCX9L: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCX9W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
